Somatic mutation profile of tumor specimen TCGA-LN-A7HV-01A (aliquot TCGA-LN-A7HV-01A-21D-A351-09) from TCGA case TCGA-LN-A7HV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 58.8 years (21,462 days).
Specimen TCGA-LN-A7HV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c099e528-e493-4af3-b0f6-c611222bcfcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A7HV-10A (Blood Derived Normal), aliquot TCGA-LN-A7HV-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdec0add-740a-4a9b-83d7-ad3d5e1a16f4

The open-access MAF lists 103 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 20, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1167609100, COSV58822670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADORA2B | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775839247; called by muse, mutect2, varscan2
- CDH7 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV59884317; called by muse, mutect2, varscan2
- COL6A6 | c.3391G>A p.D1131N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs1202254355, COSV62024213; called by muse, mutect2
- CPD | c.3383A>G p.N1128S | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.81); PolyPhen benign (0.026); catalogued as rs1252229931, COSV99852356; called by muse, mutect2, varscan2
- DTX1 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1329039766, COSV104378007; called by muse, mutect2, varscan2
- EHD3 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs778088572, COSV100434901, COSV59033506; called by muse, mutect2, varscan2
- GRXCR1 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV67670049; called by muse, mutect2, varscan2
- HNRNPM | c.1349T>G p.M450R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs1252966805; called by muse, mutect2, varscan2
- IGDCC4 | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1191516234, COSV61538192; called by muse, mutect2, varscan2
- IL37 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as rs550494451; called by muse, mutect2, varscan2
- KMT2C | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1343839780; called by muse, mutect2, varscan2
- LDLR | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as CM983962; called by mutect2, varscan2
- MARCO | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59054980; called by muse, mutect2, varscan2
- NOP9 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); catalogued as rs1330026641; called by muse, mutect2, varscan2
- PLXNB2 | c.4481del p.I1494Tfs*38 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV63780664; called by mutect2, pindel, varscan2
- POLD3 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs142882622; called by muse, mutect2, varscan2
- PSMD3 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52858535; called by muse, mutect2, varscan2
- PTPN3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV52705886; called by muse, mutect2
- RBPJL | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775667917, COSV100636921; called by muse, mutect2, varscan2
- SGSM2 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.839); catalogued as rs1226607394; called by muse, mutect2, varscan2
- SLC46A1 | c.1155G>C p.E385D | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as rs782018017; called by muse, mutect2, varscan2
- TAS2R46 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1276904411; called by muse, mutect2, varscan2
- TNN | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV53424371; called by muse, mutect2, varscan2
- TRDN | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs371627659, COSV62122937; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YTHDC2 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1175624012; called by muse, mutect2, varscan2
- ZBED8 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs775463125; called by muse, mutect2, varscan2
- ZNF750 | c.118del p.L40Ffs*5 | Frame Shift Del (DEL) | VAF 29/63 reads (46%) | catalogued as COSV53958563, COSV53959832; called by mutect2, pindel, varscan2
- ADCY9 | c.3277G>T p.D1093Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDOC | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ARHGAP12 | c.1951+1G>T p.X651_splice | Splice Site (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- ARSA | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP8B3 | c.3233T>C p.V1078A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- ATP9B | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CHD1 | c.2437A>G p.M813V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CMKLR1 | c.111G>T p.R37S (on ENST00000312143 / NM_001142344.2; = p.R35S on NM_004072.3) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- COQ8B | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CSRNP2 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- DDX60L | c.5101A>T p.S1701C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.22); called by muse, mutect2
- DENND2C | c.308A>C p.D103A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNTTIP1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSG2 | c.3320T>C p.V1107A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DST | c.2306A>G p.N769S (on ENST00000361203 / NM_001374722.1; = p.N443S on NM_001723.6) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EML4 | c.2720A>G p.N907S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM120B | c.1281G>T p.M427I | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAR1 | c.1328A>T p.K443M | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FGL1 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- GALNT17 | c.502A>T p.I168F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GNAL | c.311T>C p.V104A (on ENST00000269162 / NM_001142339.3; = p.V181A on NM_182978.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.538); called by muse, mutect2
- INSRR | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by mutect2, varscan2
- KMT2A | c.8774T>A p.L2925Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MACF1 | c.5401G>A p.D1801N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- MALT1 | c.1852A>G p.I618V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- MTMR9 | c.242T>G p.L81W | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NASP | c.605C>G p.T202S | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA4 | c.1780T>C p.F594L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NECAB3 | c.775C>G p.P259A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLGN4Y | c.1638_1644del p.F546Lfs*27 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- OR13C3 | c.440T>A p.M147K | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- OR2W3 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PFDN5 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PGAP2 | c.190A>G p.S64G (on ENST00000463452 / NM_001346398.2; = p.S125G on NM_014489.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PIK3C2G | c.2162A>G p.Y721C (on ENST00000676171; = p.Y680C on NM_004570.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PKP1 | c.1685A>G p.D562G | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PTCHD1 | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RFC1 | c.2075A>T p.E692V (on ENST00000381897 / NM_001363496.2; = p.E691V on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SHTN1 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2
- SIRPB1 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- SLC33A1 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- SMAD7 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNRPC | c.82A>T p.R28W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBRG4 | c.933_953del p.Q311_T318delinsH | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- TCF4 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRA2B | c.523-2A>G p.X175_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- TRAK1 | c.1624G>A p.E542K (on ENST00000327628 / NM_001349247.2; = p.E484K on NM_014965.5) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2
- UBA6 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- VWA3A | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ZFPM2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZNF143 | c.1406A>G p.Q469R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZNF391 | c.288A>C p.L96F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF561 | c.640A>T p.N214Y | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC130 | c.432C>T p.D144= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs768115849, COSV99681378; called by muse, mutect2, varscan2
- COL6A3 | c.6789A>T p.R2263= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CRYBG1 | c.2262C>G p.T754= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- DOCK5 | c.5049T>A p.S1683= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- HIVEP1 | c.6807G>A p.R2269= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- HS2ST1 | c.219C>T p.D73= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- INTS6L | c.2427T>A p.P809= | Silent (SNP) | VAF 59/98 reads (60%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1830C>A p.T610= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV50130416, COSV99328499; called by muse, mutect2, varscan2
- KRT13 | c.858G>A p.E286= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1389970544; called by muse, mutect2
- MYNN | c.411A>G p.E137= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1241146494; called by muse, mutect2, varscan2
- MYO9A | c.3411A>G p.E1137= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- OR10X1 | c.96C>G p.G32= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- OR2A5 | c.498G>T p.L166= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs902592910; called by muse, mutect2, varscan2
- PLEKHM2 | c.1347G>A p.P449= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs1257493374; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPS5 | c.165G>T p.R55= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- SEMA3D | c.636T>C p.D212= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs776327910, COSV52393013; called by muse, mutect2, varscan2
- SLC17A6 | c.810G>A p.K270= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV99581750; called by muse, mutect2, varscan2
- SRCAP | c.762A>G p.P254= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs764585756; called by muse, mutect2, varscan2
- TBCE | c.1380A>G p.L460= (on ENST00000366601; = p.L523= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs758366722; called by muse, mutect2, varscan2
- TREX1 | c.816T>C p.D272= (on ENST00000625293 / NM_033629.6; = p.D262= on NM_007248.5) | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- TLN2 | c.7002+3377T>G | Intron (SNP) | VAF 18/57 reads (32%) | catalogued as rs777464613; called by muse, mutect2, varscan2
